Surgical pathology report (de-identified scan), TCGA case TCGA-F1-A72C, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site UNC, specimen TCGA-F1-A72C-01A (Primary Tumor).

[page 1 of 4]
SURGICAL PATHOLOGY

Case Number :

ICD-O-3
Adenocarcinoma, intestinal
type 81441/3
Site Stomach NOS
C16.9
QW 8/9/13

Diagnosis:

A: Distal stomach with prior gastrojejunostomy, resection

Histologic tumor type/subtype: Invasive moderately
differentiated gastric adenocarcinoma, intestinal type

Histologic grade: Moderately differentiated (G2)

Tumor location: Distal stomach associated with surgical
anastomosis site

Treatment effect: N/A

Tumor Size/Depth of invasion: Maximum tumor size 5.9 x 3.6 x 2.4
cm by gross examination; tumor invades subserosal soft tissues
without involvement of visceral peritoneum

Lymphovascular invasion: Focally present

Perineural invasion: Focally present

Histologic assessment of surgical margins: All surgical
resection margins are negative; distance to closest margin 1.3
cm from proximal small bowel margin by gross examination

Proximal surgical margin: Negative

Distal surgical margin: Negative

Radial (adventitial) margin: Negative

Lymph nodes: No tumor seen in 9 lymph nodes in this specimen
(0/9); total lymph node count inclusive of specimens A and C is
no tumor seen in 13 lymph nodes (0/13)

Size of largest nodal metastasis (greatest dimension): N/A

Presence/absence of extranodal extension: N/A

Other significant findings: Chronic active gastritis; intestinal
metaplasia; intact surgical anastomosis with multifocal suture
granulomata

AJCC Pathologic Staging: pT3 pN0

[page 2 of 4]
This staging information is based on this pathologic specimen and may be incomplete. A comprehensive review of all available information is recommended to determine final staging.

B: Omentum, omentectomy

- Benign omentum with no tumor seen.

C: Lymph nodes, left gastric, regional resection

- No tumor seen in four lymph nodes (0/4).
- Sutured granulomata identified.

Comment:

The frozen section diagnosis is confirmed.

Intraoperative Consult Diagnosis:

A frozen section is requested by Dr. in OR at .

FSA1/FSA2: Stomach, proximal margin, en face

- Gastric mucosa with chronic gastritis and patchy intestinal metaplasia, no tumor seen

Drs. on at

Frozen Section Pathologist:, MD

Clinical History:

The patient is a -year-old man with gastric cancer at anastomosis. The patient is status post previous Billroth II gastrectomy approximately years ago for ulcer.

Gross Description:

Specimen A is received is one appropriately labeled container, labeled "distal stomach with prior gastrojejunostomy".

Specimen fixation: Formalin

Type of specimen: Partial gastrectomy with a portion of small bowel

Size of specimen: Stomach: 9.9 cm long x 21.6 cm in circumference, small bowel: 5.3 cm long x 9.6 cm in circumference.

Orientation of specimen: The proximal gastric margin is marked with a suture=green. The distal small bowel margin = black. The

[page 3 of 4]
proximal small bowel staple line=blue. Where the frozen section was taken = yellow. The area where the radial margin was taken = red. Serosa overlying the mass=black.

Tumor size: 5.9 x 3.6 x 2.4 cm.

Tumor description: The mass is firm, fungating with heaped borders and central ulceration. The cut surface is tan/white, firm, and smooth, with infiltrative component extending into subserosal soft tissue.

Location of tumor: Surrounding the anastomotic staple line, involving the stomach and small bowel.

Depth of invasion: The mass invades through the muscularis propria into the mesentery.

Distance of tumor from surgical margins: Radial margin 1.7 cm, proximal gastric margin-2.5 cm, distal small bowel margin 2 cm, and proximal small bowel margin 1.3 cm.

Description of remainder of tissue: At the anastomotic line, 5.0 cm from the mass is 4.5 x 1.2 cm x 0.5 cm area of raised, tan, firm mucosa. The remainder of the gastric mucosa is tan, smooth and glistening. The remainder of the small bowel mucosa is tan/brown and exhibits normal intestinal folding. The serosa is tan, smooth and glistening.

Tissue submitted for specimen investigations: Yes, tumor and normal

Lymph nodes: 14 lymph node candidates are identified in the perigastric fat ranging from 0.2 to 1 cm in greatest dimension. 16 lymph node candidates are identified in the subserosal anastomotic fat ranging from 0.2 to 0.5 cm in greatest dimension.

Other attached structures: N/A

Other comments: None

Digital photograph taken: No

Block Summary:

FSA1 - Stomach, proximal margin en face closest to mass

FSA2 - Stomach, proximal margin en face closest to mass

A3-A4 - Additional proximal margin, en face

[page 4 of 4]
A5-A6 - Distal margin, en face
A7 - Proximal small bowel margin, en face
A8 - Mesenteric margin, en face
A9-A10 - Deepest invasion of mass, bisected, perpendicular
A11 - Additional deepest invasion of mass, perpendicular
A12 - Mass in relation to normal stomach
A13 - Mass in relation to normal intestine
A14 - Nodularity along anastomotic line
A15 - Multiple lymph node candidates
A16 - Four perigastric lymph node candidates
A17 - Four perigastric lymph node candidates
A18 - Six anastomotic site lymph node candidates
A19 - Six anastomotic site lymph node candidates
A20 - Four anastomotic site lymph node candidates

Specimen B is labeled with the patient's name and "omentum" and is a 29.8 x 10.9 x 2.5 cm portion of yellow lobulated adipose tissue. There are no areas of fibrosis or gross lesions noted. Representative sections are submitted in block B1.

Specimen C is labeled with the patient's name and "left gastric lymph nodes" and is a 5.5 x 3.9 x 2 cm portion of tan/yellow fibroadipose tissue. Six lymph nodes are identified ranging in size from 0.5 to 1.1 cm in greatest dimension. The remaining fibroadipose tissue is retained in the container.

Block Summary:

C1 - One lymph node, serially sectioned
C2 - One lymph node, serially sectioned
C3 - Four lymph node candidates

Histo Discrepancy		✓

Source: NCI Genomic Data Commons file bd414b6f-ced5-4826-8703-9370e150644f (TCGA-F1-A72C.92332E07-96A1-4399-8348-E670E8A67CE9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).